Somatic mutation profile of tumor specimen MP2PRT-PAVHLK-TMP1-A (aliquot MP2PRT-PAVHLK-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHLK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,740 days).
Specimen MP2PRT-PAVHLK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e0742dd-d8c9-46ab-a99f-bdb580029adb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHLK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHLK-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2931316e-5af9-4843-8eb0-e3c228a3d5e7

The open-access MAF lists 39 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 8, Nonsense Mutation 2, In Frame Ins 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 15/252 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 35/296 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ADAMTS9 | c.5170C>T p.R1724* | Nonsense Mutation (SNP) | VAF 117/278 reads (42%) | catalogued as rs762379587; called by muse, mutect2, varscan2
- AFF1 | c.1627G>A p.E543K | Missense Mutation (SNP) | VAF 34/548 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.451); catalogued as COSV57125336; called by muse, mutect2
- ALDH1A1 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV52790923; called by muse, mutect2, varscan2
- CASZ1 | c.3271C>T p.P1091S | Missense Mutation (SNP) | VAF 82/578 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs766384219; called by muse, mutect2
- FUT8 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV61292681; called by muse, mutect2, varscan2
- KDM5C | c.1762C>A p.Q588K | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV64771432; called by muse, mutect2, varscan2
- LOX | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 44/596 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1321560490; called by muse, mutect2
- NFATC4 | c.2630C>T p.T877M | Missense Mutation (SNP) | VAF 60/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747289825; called by muse, mutect2, varscan2
- SLC36A2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 23/352 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs969941163; called by muse, mutect2
- SS18L1 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 122/269 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV59211591; called by muse, mutect2, varscan2
- ANK3 | c.8659G>A p.E2887K | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- ANK3 | c.6059C>A p.A2020E | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ARID2 | c.4156G>T p.G1386* | Nonsense Mutation (SNP) | VAF 13/268 reads (5%) | called by muse, mutect2
- B4GALNT1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- BSN | c.10593C>G p.F3531L | Missense Mutation (SNP) | VAF 121/323 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- BSN | c.11161A>C p.S3721R | Missense Mutation (SNP) | VAF 151/401 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CC2D2B | c.1642G>C p.E548Q | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- EDC3 | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 53/349 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- EPHA3 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GDF7 | c.127_128insTCGGCG p.G42_G43insVG | In Frame Ins (INS) | VAF 79/156 reads (51%) | called by mutect2, varscan2*
- GPATCH2 | c.1058C>T p.S353L | Missense Mutation (SNP) | VAF 70/314 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- OR8I2 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- P3H1 | c.488T>C p.V163A | Missense Mutation (SNP) | VAF 89/204 reads (44%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PNLIPRP1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.181); called by muse, mutect2
- SCG2 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 23/381 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.451); called by muse, mutect2
- TAF4 | c.437_439del p.V146del | In Frame Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- ZNF66 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZNF829 | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ALPL | c.1470C>T p.I490= | Silent (SNP) | VAF 50/652 reads (8%) | catalogued as rs771120248, COSV66376165; ClinVar: likely benign; called by muse, mutect2
- CADPS2 | c.390C>T p.L130= | Silent (SNP) | VAF 16/353 reads (5%) | catalogued as rs1287676314, COSV57364422; called by muse, mutect2
- CNP | c.459G>A p.A153= | Silent (SNP) | VAF 36/326 reads (11%) | catalogued as rs370119358; called by muse, mutect2, varscan2
- DYRK1B | c.1614C>T p.T538= | Silent (SNP) | VAF 71/468 reads (15%) | catalogued as rs771204068, COSV59914358; called by muse, mutect2, varscan2
- GNA14 | c.684G>C p.L228= | Silent (SNP) | VAF 100/226 reads (44%) | catalogued as rs377242581; called by muse, mutect2, varscan2
- HSBP1 | c.192G>A p.L64= | Silent (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- MAGEB10 | c.504G>A p.L168= | Silent (SNP) | VAF 42/236 reads (18%) | catalogued as COSV63312793; called by muse, mutect2, varscan2
- SH3RF2 | c.246C>T p.S82= | Silent (SNP) | VAF 41/499 reads (8%) | catalogued as rs1156459483; called by muse, mutect2
- IGKV3-20 | chr2:89142573 ins TGGA | 3'Flank (INS) | VAF 19/37 reads (51%) | called by mutect2, varscan2*
